Gene-level copy-number profile of tumor specimen TCGA-13-1505-01A from TCGA case TCGA-13-1505, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.6 years (23,238 days).
Specimen TCGA-13-1505-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.41b3be7d-4f77-4065-af1b-a054a17e3810.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-1505-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 367 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eac62560-f566-44bd-8b6c-07c811b4dd98

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1,066; copy number 1: 7,448; copy number 2: 18,744; copy number 3: 21,340; copy number 4: 7,882; copy number 5: 1,696; copy number 6: 1,344; copy number 7: 237; copy number 8: 313; copy number 9: 95; copy number 10: 49; copy number 11: 6; copy number 12: 18; copy number 14: 11; copy number 15: 1; copy number 20: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-1505-01A-01D-0472-01): tumor purity 0.87, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 736 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:38,859,912–38,965,038, 1 gene, copy number 8 (within-gene range 6–8): AL139260.1.
- chr1:38,885,807–44,844,082, 215 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr2:88,811,186–88,861,563, 1 gene, copy number 10 (within-gene range 4–10): AC244205.1.
- chr2:88,857,161–89,046,466, 20 genes, copy number 10: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13.
- chr2:183,253,652–183,495,501, 1 gene, copy number 7 (within-gene range 4–7): AC021851.2.
- chr2:183,607,442–184,939,492, 10 genes, copy number 7: CACYBPP2, AC093639.3, AC093639.1, AC093639.2, AC096555.1, AC020584.1, MIR548AE1, AC096667.1, ZNF804A, RPL23AP33.
- chr2:214,931,542–215,138,626, 2 genes, copy number 8 (within-gene range 6–8): ABCA12, AC072062.1.
- chr3:112,815,709–113,184,377, 9 genes, copy number 7: CD200R1L, CD200R1, AC074044.1, GTPBP8, NEPRO, AC078785.1, AC078785.3, AC078785.2, LINC02044.
- chr3:165,122,713–166,862,110, 19 genes, copy number 7: Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1.
- chr3:183,015,218–183,116,075, 1 gene, copy number 7 (within-gene range 6–7): MCCC1.
- chr3:183,122,215–183,684,519, 14 genes, copy number 7–9: LAMP3, MCF2L2, B3GNT5, RNA5SP151, LINC00888, SNORA63D, AC092960.2, SNORA63E, AC092960.1, AC092960.3, KLHL6, KLHL6-AS1, AC068769.1, KLHL24.
- chr6:37,170,152–38,154,624, 21 genes, copy number 7 (within-gene range 6–7): PIM1, TMEM217, AL353579.1, TBC1D22B, AL096712.1, AL096712.2, RNF8, RN7SL273P, CMTR1, CCDC167, LINC02520, AL353597.2, AL353597.1, MIR4462, AL353597.3, MDGA1, AL121574.1, ZFAND3, RN7SL285P, RNVU1-33, AL589655.1.
- chr6:38,923,029–39,322,968, 9 genes, copy number 7: DNAH8-AS1, AL034345.1, AL035690.1, GLP1R, SAYSD1, ANKRD18EP, KCNK5, KCNK17, KCNK16.
- chr6:41,546,426–43,308,826, 67 genes, copy number 8–12 (within-gene range 5–12) (broad region; genes not listed).
- chr6:43,310,231–43,310,357, 1 gene, copy number 10: RPL12P47.
- chr6:46,746,917–54,771,134, 138 genes, copy number 7–9 (within-gene range 2–9) (broad region; genes not listed).
- chr10:6,682,513–8,016,631, 21 genes, copy number 7–20 (within-gene range 2–20): AL158210.1, LINP1, AL392086.2, LINC00706, LINC00707, AL392086.1, AL392086.3, LINC02665, AL590095.1, SFMBT2, COX6CP17, AL139125.1, LINC02642, RNU6-535P, AL445070.1, ITIH5, ITIH2, KIN, ATP5F1C, TAF3, AL353754.1.
- chr10:10,058,722–12,835,545, 37 genes, copy number 8–9 (within-gene range 6–9): LINC02670, ELOCP3, Y_RNA, CUX2P1, AL354916.1, AL583859.1, CELF2-DT, AL583859.2, AL583859.3, AL136452.1, SFTA1P, CELF2, LINC00710, AL136369.2, AL136369.1, AL162408.1, CELF2-AS2, AL136320.1, CELF2-AS1, AC026887.1, USP6NL, AL512631.2, AL512631.1, ECHDC3, PROSER2, PROSER2-AS1, UPF2, RNU6-1095P, DHTKD1, RNU6-88P, SEC61A2, MIR548AK, NUDT5, CDC123, AL512770.1, RN7SL198P, CAMK1D.
- chr10:12,563,151–14,774,897, 45 genes, copy number 7–10: AL731559.1, MIR4480, MIR4481, MIR548Q, AL353586.1, CCDC3, RNA5SP300, RPL5P25, OPTN, SNRPGP5, AL355355.2, AL355355.1, BTBD7P1, RPL36AP36, MCM10, RNU6-6P, UCMA, PHYH, RBISP1, SEPHS1, AL355870.2, AL355870.1, BEND7, Y_RNA, AL590677.1, PRPF18, RPL6P24, AL157392.5, AL157392.3, FRMD4A, AL157392.4, AL157392.1, RNA5SP301, AL157392.2, NUTF2P5, AC044781.1, AL157896.1, AL139405.1, MIR4293, Metazoa_SRP, MIR1265, FAM107B, AL158168.1, RNA5SP302, RPSAP7.
- chr10:37,523,011–38,466,176, 32 genes, copy number 7–8: TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1.
- chr21:15,067,070–16,645,467, 23 genes, copy number 9 (within-gene range 4–9): AF127577.5, AF222684.1, AF222685.1, AF130248.1, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P, RAD23BP3, USP25, RBPMSLP, MIR99AHG, RNU6-426P, VDAC2P1, RPS26P5, SNORD74B, AP001172.1, AP001172.2, AP000962.3, AP000962.2, MIR99A, MIRLET7C.
- chr21:19,593,841–23,889,150, 43 genes, copy number 7–14: RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683, LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1, NCAM2, AP001136.1, AP001117.1, AF241725.1, LINC00317, LINC01425, AP000472.1, LINC01687, LINC00308, AP000705.2, AP000705.1, RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000961.1, AP000474.2.
- chr21:25,639,258–25,717,562, 1 gene, copy number 11 (within-gene range 6–11): JAM2.
- chr21:25,646,113–25,772,460, 5 genes, copy number 11 (within-gene range 6–11): AP000224.1, FDX1P2, ATP5PF, GABPA, LLPHP2.

Autosomal genes at a single copy (total copy number 1): 7,437. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
